Somatic mutation profile of tumor specimen TCGA-DA-A960-01A (aliquot TCGA-DA-A960-01A-11D-A372-08) from TCGA case TCGA-DA-A960, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 74.2 years (27,104 days).
Specimen TCGA-DA-A960-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfd69f83-8385-4241-9c36-816b38ef1458.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A960-10A (Blood Derived Normal), aliquot TCGA-DA-A960-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4c8c57d-49f0-4c20-a30a-1c9877fda945

The open-access MAF lists 1,045 somatic variants for this specimen: 676 protein-altering or splice-affecting, 347 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 612, Silent 347, Nonsense Mutation 33, Splice Region 16, Intron 13, Splice Site 7, Frame Shift Del 4, RNA 4, 3'UTR 3, 3'Flank 2, In Frame Ins 1, In Frame Del 1.

Variants (750 of 1,045; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121908217, CM994288, COSV100800683, COSV100803453; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.6388G>A p.E2130K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs794728334, CM067392, COSV57317339; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FIG4 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 58/235 reads (25%) | catalogued as rs753207473, COSV57785952; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- MYO18B | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 43/89 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.67); PolyPhen benign (0.344); catalogued as COSV100123667, COSV59127388; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 104/157 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 66/106 reads (62%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- AAK1 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV101275837; called by muse, mutect2, varscan2
- ABCA1 | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs776200971, COSV101036453; called by muse, mutect2, varscan2
- ABCA13 | c.5456T>C p.F1819S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV101329911; called by muse, mutect2, varscan2
- ABCB1 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99712021; called by muse, mutect2, varscan2
- ABCB5 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99327307; called by muse, mutect2, varscan2
- ABCC12 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV60916057, COSV60916782; called by muse, mutect2, varscan2
- ABI3BP | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs1361342213, COSV52551469; called by muse, mutect2, varscan2
- AC109583.1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.337); catalogued as rs944176654, COSV100167774; called by muse, mutect2, varscan2
- ACE2 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99382508; called by muse, mutect2, varscan2
- ACSM4 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV101257000; called by muse, mutect2, varscan2
- ACTRT2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs780802847, COSV65760099; called by muse, mutect2, varscan2
- ADAM18 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 73/105 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1237620543, COSV99694770; called by muse, mutect2, varscan2
- ADAM2 | c.1814G>A p.R605K | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99696648; called by muse, mutect2, varscan2
- ADAM2 | c.190A>C p.N64H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.722); catalogued as rs1248751167, COSV55861499; called by muse, mutect2, varscan2
- ADAMTS18 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867875220, COSV51406551; called by muse, mutect2, varscan2
- ADAMTS18 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs199984064, COSV51399377; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1034A>C p.Q345P | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99716767; called by muse, mutect2, varscan2
- ADCK1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.017); catalogued as COSV99450839; called by muse, mutect2, varscan2
- ADCY2 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202064623, COSV57876522; called by muse, mutect2, varscan2
- ADCY7 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs867921171, COSV54266876; called by muse, mutect2, varscan2
- ADGRG2 | c.310A>G p.K104E (on ENST00000379869 / NM_001079858.3; = p.K101E on NM_005756.4) | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100491844; called by muse, mutect2, varscan2
- ADGRL3 | c.1555C>G p.P519A (on ENST00000506720 / NM_001322402.2; = p.P451A on NM_015236.6) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101546833; called by muse, mutect2, varscan2
- ADGRV1 | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101315432; called by muse, mutect2, varscan2
- ADGRV1 | c.6055G>A p.D2019N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.348); catalogued as rs201086252, COSV101315433; called by muse, mutect2, varscan2
- AFF1 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.418); catalogued as rs775143095, COSV100320171; called by muse, mutect2, varscan2
- AJAP1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100981481; called by muse, mutect2, varscan2
- AKAP5 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100277844; called by muse, mutect2, varscan2
- ALAS2 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.16); PolyPhen benign (0.421); catalogued as COSV100237917; called by muse, mutect2, varscan2
- ALB | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as CM050168, COSV99890637; called by muse, mutect2, varscan2
- ALK | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66590989; called by muse, mutect2, varscan2
- AMER2 | c.1331C>A p.S444Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100766123; called by muse, mutect2, varscan2
- AMER2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs138062625; called by muse, mutect2, varscan2
- AMIGO2 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 98/112 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV104384698, COSV99873413; called by muse, mutect2, varscan2
- ANK3 | c.3487C>T p.Q1163* (on ENST00000280772 / NM_001320874.2; = p.Q297* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as COSV55070310; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3319C>T p.L1107F | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99781932; called by muse, mutect2, varscan2
- ANKIB1 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV56066437; called by muse, mutect2
- ANKRD12 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.109); catalogued as rs142355341; called by muse, mutect2, varscan2
- ANKRD50 | c.2209C>G p.R737G | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs1377673439, COSV101538877, COSV72385130; called by muse, mutect2, varscan2
- ANKS1B | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV61351854; called by muse, mutect2, varscan2
- ANO2 | c.2734C>T p.L912F (on ENST00000356134 / NM_001278597.3; = p.L916F on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs1416023550, COSV100499651, COSV100499750; called by muse, mutect2, varscan2
- AQP1 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100310821; called by muse, mutect2, varscan2
- AQP1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968619407, COSV100310824; called by muse, mutect2, varscan2
- AQP9 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs367676440, COSV54968868; called by muse, mutect2, varscan2
- ARAP2 | c.3261G>A p.G1087= | Splice Region (SNP) | VAF 31/153 reads (20%) | catalogued as rs571642187, COSV100394053; called by muse, mutect2, varscan2
- ARHGAP22 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50967170; called by muse, mutect2, varscan2
- ARID2 | c.4515del p.T1506Qfs*10 | Frame Shift Del (DEL) | VAF 66/101 reads (65%) | catalogued as COSV100537110; called by mutect2, pindel, varscan2
- ASGR1 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99352395; called by muse, mutect2, varscan2
- ASIC1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs775952643, COSV57318035; called by muse, mutect2, varscan2
- ASRGL1 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV100077651; called by muse, mutect2
- ASTN1 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV99920332; called by muse, mutect2
- ASXL3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as rs749484741, COSV52457610; called by muse, mutect2, varscan2
- ATP6AP2 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101011432, COSV65797478; called by muse, mutect2, varscan2
- ATXN2 | c.2746C>T p.P916S (on ENST00000550104; = p.P756S on NM_002973.4) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101112565; called by muse, mutect2, varscan2
- ATXN7L2 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100881304; called by muse, mutect2, varscan2
- AVPR1B | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs782574482, COSV100899299; called by muse, mutect2, varscan2
- B3GNT5 | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV100191133; called by muse, mutect2, varscan2
- BFAR | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55494614; called by muse, mutect2, varscan2
- BHLHE40 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56576681, COSV99847911; called by muse, mutect2, varscan2
- BICRA | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.685); catalogued as rs368458943, COSV101194220; called by muse, varscan2
- BIRC3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 91/170 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54815220; called by muse, mutect2, varscan2
- BLK | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52051973; called by muse, mutect2, varscan2
- BMPER | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV99778802; called by muse, mutect2, varscan2
- BPI | c.359G>A p.G120E (on ENST00000262865; = p.G116E on NM_001725.3) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99480371; called by muse, mutect2, varscan2
- BRINP1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); catalogued as rs151087333, COSV56292314; called by muse, mutect2, varscan2
- BTBD11 | c.3079T>G p.C1027G (on ENST00000280758 / NM_001018072.2; = p.C564G on NM_001017523.2) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99774658; called by muse, mutect2, varscan2
- BTNL8 | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.748); catalogued as rs773723596, COSV51460857, COSV99180419; called by muse, mutect2, varscan2
- C3 | c.4309G>A p.A1437T | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as rs1432105397, COSV99835989; called by muse, mutect2, varscan2
- C6orf118 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100023992; called by muse, mutect2, varscan2
- C7orf26 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.426); catalogued as rs887207404, COSV100732823; called by muse, mutect2, varscan2
- C8B | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs866652259, COSV64780233; called by muse, mutect2, varscan2
- CACNA1D | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99856478; called by muse, mutect2, varscan2
- CACNA1D | c.6374G>A p.R2125Q (on ENST00000350061 / NM_001128840.3; = p.R2145Q on NM_000720.4) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as rs753048719, COSV99856487; called by muse, mutect2, varscan2
- CACNA1E | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 49/89 reads (55%) | catalogued as COSV100701265; called by muse, mutect2, varscan2
- CACNA1H | c.7051G>A p.D2351N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1181185791, COSV99326298; called by muse, mutect2
- CACNA1S | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs1419615703, COSV100754618; called by muse, mutect2, varscan2
- CACNA2D4 | c.2690G>A p.G897E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767183420, COSV99764996; called by muse, mutect2, varscan2
- CAD | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254357; called by muse, mutect2, varscan2
- CADM2 | c.586G>A p.D196N (on ENST00000407528 / NM_001167674.2; = p.D198N on NM_153184.4) | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101052657; called by muse, mutect2, varscan2
- CALB2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV56938147; called by muse, mutect2, varscan2
- CALCRL | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406951346, COSV101130875; called by muse, mutect2, varscan2
- CAMK4 | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV99998210; called by muse, mutect2, varscan2
- CAMKV | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as rs1241766696, COSV99615037; called by muse, mutect2, varscan2
- CASR | c.2068G>A p.E690K (on ENST00000490131; = p.E767K on NM_000388.4) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as CM050191, CM106568, COSV56136585, COSV99949724; called by muse, mutect2, varscan2
- CATSPERD | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs745670557, COSV58465097; called by muse, mutect2, varscan2
- CCDC141 | c.3748G>T p.G1250W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV55373317; called by muse, mutect2, varscan2
- CCDC158 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV101187141; called by muse, mutect2, varscan2
- CCDC172 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100319630, COSV60939872; called by muse, mutect2, varscan2
- CCDC178 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.103); catalogued as rs1313119060, COSV100283157; called by muse, mutect2, varscan2
- CCDC185 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs560005249, COSV100838738, COSV64820394; called by muse, mutect2, varscan2
- CCDC68 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV100491591; called by muse, mutect2, varscan2
- CCDC83 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1343772118, COSV54701403; called by muse, mutect2, varscan2
- CCKBR | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.146); catalogued as rs1372506488, COSV58102293; called by muse, mutect2, varscan2
- CCNF | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV99563096; called by muse, mutect2
- CCP110 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as COSV101195212; called by muse, mutect2, varscan2
- CD200R1L | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV68003808; called by muse, mutect2, varscan2
- CDC23 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV101203077; called by muse, mutect2, varscan2
- CDC73 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.315); catalogued as COSV66469097; called by muse, mutect2, varscan2
- CDCA8 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs762302397, COSV100523498; called by muse, mutect2, varscan2
- CDH13 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51857086, COSV99222076; called by muse, mutect2, varscan2
- CDH17 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as COSV99216918; called by muse, mutect2, varscan2
- CDH20 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs758510987, COSV53004764, COSV53005466; called by muse, mutect2, varscan2
- CDHR2 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV99990963; called by muse, mutect2, varscan2
- CECR2 | c.2264C>T p.P755L (on ENST00000342247 / NM_001290047.2; = p.P572L on NM_001290046.1) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1003666211, COSV99376890; called by muse, mutect2
- CEMIP | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 127/205 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.272); catalogued as COSV54998270; called by muse, mutect2, varscan2
- CEP126 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54825377; called by muse, mutect2, varscan2
- CEP192 | c.5822C>T p.P1941L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV100380523, COSV58070301; called by muse, mutect2, varscan2
- CFAP47 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as rs779460237, COSV99934292; called by muse, mutect2, varscan2
- CFH | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV66414666; called by muse, mutect2, varscan2
- CHAF1B | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023321; called by muse, mutect2, varscan2
- CHAMP1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 89/511 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100778712; called by muse, mutect2, varscan2
- CHAMP1 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 90/509 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1173710981, COSV100778713; called by muse, mutect2, varscan2
- CHD4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs754152386, COSV100537253; called by muse, mutect2, varscan2
- CHGB | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV66761628; called by muse, varscan2
- CHP2 | c.222G>A p.G74= | Splice Region (SNP) | VAF 43/80 reads (54%) | catalogued as COSV100270031; called by muse, mutect2, varscan2
- CHRNB4 | c.1341C>T p.V447= | Splice Region (SNP) | VAF 21/24 reads (88%) | catalogued as rs71534215, COSV99929123; called by muse, mutect2, varscan2
- CHST15 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1486381652, COSV100654912; called by muse, mutect2, varscan2
- CHSY3 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV100518422; called by muse, mutect2, varscan2
- CLEC18A | c.327C>A p.N109K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99846834; called by muse, mutect2, varscan2
- CLEC4C | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.528); catalogued as rs867782925, COSV100665342; called by muse, mutect2, varscan2
- CLIC5 | c.889G>A p.E297K (on ENST00000185206 / NM_001370649.1; = p.E138K on NM_016929.5) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV99483725; called by muse, mutect2, varscan2
- CMYA5 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs779242405, COSV101483800; called by muse, mutect2, varscan2
- CNTN3 | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55176041; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, varscan2
- CNTNAP2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1004911642, COSV62152199, COSV62174516; called by muse, varscan2
- CNTNAP5 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.117); catalogued as COSV101442997, COSV101443734; called by muse, mutect2, varscan2
- COL4A6 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 71/82 reads (87%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV100563253; called by muse, mutect2, varscan2
- COL5A2 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66414347; called by muse, mutect2
- COLEC11 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as COSV99362797; called by muse, mutect2, varscan2
- CORIN | c.819G>C p.E273D | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV56695610, COSV99902799; called by muse, mutect2, varscan2
- CPAMD8 | c.1187C>T p.S396F (on ENST00000651564; = p.S349F on NM_015692.5) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99358921; called by muse, mutect2, varscan2
- CPE | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297830313, COSV101291540; called by muse, mutect2, varscan2
- CRB1 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100958300; called by muse, mutect2, varscan2
- CSHL1 | c.367T>C p.F123L (on ENST00000309894 / NM_022581.3; = p.F29L on NM_001318.4) | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1159767814, COSV99367761; called by muse, mutect2, varscan2
- CSMD1 | c.7844G>A p.R2615K (on ENST00000520002; = p.R2614K on NM_033225.6) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV100143090; called by muse, mutect2, varscan2
- CSMD2 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1356557694, COSV53912898; called by muse, mutect2, varscan2
- CSMD3 | c.11020C>T p.Q3674* (on ENST00000297405 / NM_001363185.1; = p.Q3505* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 41/223 reads (18%) | catalogued as COSV99823496; called by muse, mutect2, varscan2
- CSTL1 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as rs1468704981, COSV99851053, COSV99851091; called by muse, mutect2, varscan2
- CTAGE1 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs752410629, COSV101194423; called by muse, mutect2
- CUBN | c.7846C>T p.H2616Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100912018, COSV99060774; called by muse, mutect2, varscan2
- CWH43 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV99892721; called by muse, mutect2, varscan2
- DAOA | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV61602449; called by muse, mutect2, varscan2
- DARS1 | c.1367T>A p.I456N | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99927288; called by muse, mutect2, varscan2
- DAW1 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100005807; called by muse, mutect2, varscan2
- DBF4B | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 107/115 reads (93%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV100154259; called by muse, mutect2, varscan2
- DBX2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV60339452; called by muse, mutect2, varscan2
- DCAF4L1 | c.675T>G p.S225R | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100295513; called by muse, mutect2, varscan2
- DCANP1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV72345886; called by muse, varscan2
- DCC | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV71428912, COSV71441321; called by muse, mutect2, varscan2
- DCX | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV57576180; called by muse, mutect2, varscan2
- DDX1 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51839923; called by muse, mutect2, varscan2
- DEFB116 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 48/280 reads (17%) | catalogued as rs756559816, COSV68722321; called by muse, mutect2, varscan2
- DENND2C | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs368021056, COSV101283898; called by muse, mutect2, varscan2
- DENND6A | c.516C>T p.S172= | Splice Region (SNP) | VAF 9/39 reads (23%) | catalogued as rs1486128319, COSV100231239; called by muse, mutect2, varscan2
- DGKG | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99402338, COSV99403821; called by muse, mutect2, varscan2
- DISP3 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53834870; called by muse, mutect2
- DLG5 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1194071297, COSV100967228; called by muse, mutect2, varscan2
- DNAH10 | c.1988A>C p.Q663P (on ENST00000409039; = p.Q602P on NM_207437.3) | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101291916; called by muse, mutect2, varscan2
- DNAH3 | c.10223C>T p.P3408L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54536015, COSV99764753; called by muse, mutect2, varscan2
- DNAH5 | c.13276G>A p.E4426K | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs777295839, COSV54202122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.5771G>A p.G1924E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318626642, COSV100413722; called by muse, mutect2, varscan2
- DNAH8 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543127, COSV59435956; called by muse, mutect2, varscan2
- DNAJC16 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65448583; called by muse, mutect2, varscan2
- DPEP2 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52055919; called by muse, mutect2, varscan2
- DPP10 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100058060, COSV59685352; called by muse, mutect2, varscan2
- DPPA2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs780208223, COSV72117932; called by muse, mutect2, varscan2
- DPPA4 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59510134; called by muse, mutect2, varscan2
- DPYSL3 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100574875; called by muse, mutect2, varscan2
- DRD4 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs1362775428, COSV99448405; called by muse, mutect2, varscan2
- DRP2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 128/141 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371570852, COSV100871779; called by muse, mutect2, varscan2
- DSC2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99199453; called by muse, mutect2, varscan2
- DSCAM | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258986, COSV101261896; called by muse, mutect2, varscan2
- DSCAML1 | c.4333G>A p.D1445N (on ENST00000321322; = p.D1385N on NM_020693.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100354448; called by muse, mutect2, varscan2
- DSG4 | c.1983A>C p.E661D | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV100355266; called by muse, mutect2, varscan2
- DST | c.9800G>A p.R3267K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs778659217, COSV99750596; called by muse, mutect2, varscan2
- E2F8 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1402658999, COSV100001262; called by muse, mutect2, varscan2
- EBF2 | c.352+1G>A p.X118_splice | Splice Site (SNP) | VAF 16/82 reads (20%) | catalogued as rs778383492, COSV101282089; called by muse, mutect2, varscan2
- ECHDC2 | c.484G>A p.E162K (on ENST00000371522 / NM_001198961.2; = p.E131K on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100597429, COSV100597795; called by muse, mutect2, varscan2
- EDNRA | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 86/173 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV100163189; called by muse, mutect2, varscan2
- EFEMP1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100816718; called by muse, mutect2, varscan2
- EIF2B4 | c.1060C>T p.R354W (on ENST00000347454 / NM_001034116.2; = p.R353W on NM_015636.3) | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs779319688, COSV99277235; called by muse, mutect2, varscan2
- EIF4G2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100379341; called by muse, mutect2, varscan2
- ELL2 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV99427167; called by muse, mutect2, varscan2
- ELMO1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as rs1384206207, COSV100163081; called by muse, mutect2, varscan2
- EML4 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV59301507; called by muse, mutect2, varscan2
- ENAM | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867649884, COSV101252908; called by muse, mutect2, varscan2
- ENKUR | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); catalogued as COSV100482026; called by muse, mutect2, varscan2
- ENPEP | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV99486960; called by muse, mutect2, varscan2
- EPB42 | c.1670C>T p.P557L (on ENST00000441366 / NM_001114134.2; = p.P587L on NM_000119.3) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as rs960007262, COSV100281772; called by muse, mutect2, varscan2
- EPHA2 | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 66/101 reads (65%) | catalogued as rs1257908263, COSV100626010; called by muse, mutect2, varscan2
- EPHA6 | c.3092C>T p.P1031L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67588279; called by muse, mutect2, varscan2
- ERC2 | c.2715C>A p.T905= | Splice Region (SNP) | VAF 42/168 reads (25%) | catalogued as COSV99880637; called by muse, mutect2, varscan2
- EVI5 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as rs866747676, COSV100945016; called by muse, mutect2, varscan2
- EXOC1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100637742; called by muse, mutect2, varscan2
- EYA4 | c.1756+1G>A p.X586_splice (on ENST00000531901 / NM_001301013.1; = p.X580_splice on NM_004100.5) | Splice Site (SNP) | VAF 50/135 reads (37%) | catalogued as COSV100765140; called by muse, mutect2, varscan2
- F2 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319311; called by muse, mutect2, varscan2
- FAM107B | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV51679057; called by muse, mutect2, varscan2
- FAM135B | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs781523806, COSV52704264; called by muse, mutect2, varscan2
- FAM135B | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV52745533, COSV99418370; called by muse, mutect2, varscan2
- FAM47A | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV60499203, COSV60500380; called by muse, mutect2, varscan2
- FAM47C | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100792260; called by muse, varscan2
- FAM81B | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV99352492; called by muse, mutect2, varscan2
- FAM83B | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100173984; called by muse, mutect2, varscan2
- FAM83C | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV100981508; called by muse, mutect2, varscan2
- FASTKD1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs777321484, COSV70006624; called by muse, mutect2, varscan2
- FAT4 | c.13955C>T p.S4652L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV58680974, COSV58701419; called by muse, mutect2, varscan2
- FBN2 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV99324669; called by muse, mutect2, varscan2
- FCF1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100356649; called by muse, mutect2, varscan2
- FCRL6 | c.1148-1G>A p.X383_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100220014; called by muse, mutect2, varscan2
- FER1L5 | c.4784G>T p.G1595V (on ENST00000623019; = p.G1568V on NM_001293083.2) | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101208799; called by muse, mutect2, varscan2
- FILIP1 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as rs770586450, COSV52723632; called by muse, mutect2, varscan2
- FLII | c.3490_3493del p.T1164Vfs*14 | Frame Shift Del (DEL) | VAF 32/58 reads (55%) | catalogued as rs1190499939; called by mutect2, pindel, varscan2
- FLNC | c.6680G>A p.G2227D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV100367587; called by muse, mutect2, varscan2
- FREM1 | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101083709; called by muse, mutect2, varscan2
- FREM1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs772215299, COSV101085775, COSV66518648; called by muse, mutect2, varscan2
- FREM2 | c.4030C>T p.R1344C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs114409305, COSV54831462; called by muse, mutect2, varscan2
- FRRS1L | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs368103132, COSV101643892; called by muse, mutect2, varscan2
- FSIP2 | c.17382G>A p.M5794I | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100553797; called by muse, mutect2, varscan2
- FSIP2 | c.19682G>A p.R6561K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100553799; called by muse, mutect2, varscan2
- GABRA6 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs778895828, COSV50886468; called by muse, mutect2, varscan2
- GABRB2 | c.1499C>T p.S500F (on ENST00000274547; = p.S462F on NM_000813.3) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); catalogued as COSV50903913; called by muse, mutect2, varscan2
- GABRB2 | c.1373G>A p.R458Q (on ENST00000274547; = p.R420Q on NM_000813.3) | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs80241240, COSV50918104; called by muse, mutect2, varscan2
- GABRG2 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 68/135 reads (50%) | catalogued as COSV100729486, COSV62720379; called by muse, mutect2, varscan2
- GALNT13 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101222115, COSV67209645; called by muse, mutect2, varscan2
- GALNTL5 | c.660G>A p.G220= | Splice Region (SNP) | VAF 21/53 reads (40%) | catalogued as COSV101217671, COSV101217765; called by muse, mutect2, varscan2
- GAPVD1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99782594; called by muse, mutect2, varscan2
- GARNL3 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100149873; called by muse, mutect2, varscan2
- GBP3 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1357084373, COSV99352332; called by muse, mutect2, varscan2
- GBP6 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV100969456; called by muse, mutect2, varscan2
- GDI2 | c.699A>T p.E233D | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV101200717; called by muse, mutect2, varscan2
- GJB4 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201808762, COSV100258240; called by muse, mutect2, varscan2
- GLIS3 | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV100173201; called by muse, mutect2, varscan2
- GLRA1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99199405; called by muse, mutect2, varscan2
- GLRA2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 64/67 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99490156; called by muse, mutect2, varscan2
- GLRA3 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); catalogued as COSV56866919, COSV99926886; called by muse, mutect2, varscan2
- GNAL | c.763G>A p.E255K (on ENST00000269162 / NM_001142339.3; = p.E332K on NM_182978.4) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV99303009; called by muse, mutect2, varscan2
- GNL2 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1228120764, COSV99953454; called by muse, mutect2, varscan2
- GPATCH8 | c.4192C>T p.H1398Y | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV59198335; called by muse, mutect2, varscan2
- GPCPD1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100980067; called by muse, mutect2, varscan2
- GPR149 | c.1176C>A p.I392= | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as rs199768432, COSV101078086; called by muse, mutect2, varscan2
- GPR152 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs1181730727, COSV100351405; called by muse, mutect2, varscan2
- GPRASP2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs764068856, COSV100176518; called by muse, mutect2, varscan2
- GRB7 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 160/179 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100485359; called by muse, mutect2, varscan2
- GRHL1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61410055; called by muse, mutect2, varscan2
- GRIA1 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99597916; called by muse, mutect2, varscan2
- GRID1 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749158204, COSV100021694; called by muse, mutect2, varscan2
- GRIN1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.356); catalogued as COSV100159764; called by muse, mutect2, varscan2
- GRIN2A | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.122); catalogued as COSV58021321; called by muse, mutect2, varscan2
- GRIN2A | c.2596-1G>A p.X866_splice | Splice Site (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100410127, COSV58045019; called by muse, mutect2, varscan2
- GRM3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.88); PolyPhen benign (0.155); catalogued as COSV64471988; called by muse, mutect2, varscan2
- GRM7 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100735523; called by muse, mutect2, varscan2
- GRM7 | c.1151A>G p.E384G | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.098); catalogued as COSV100735524; called by muse, mutect2, varscan2
- GTDC1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs376203308; called by muse, mutect2, varscan2
- GUF1 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.998); catalogued as COSV99876985; called by muse, mutect2, varscan2
- GYS2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.1); catalogued as COSV99679397; called by muse, mutect2, varscan2
- HCK | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189947820, COSV52942388; called by muse, mutect2, varscan2
- HEATR5B | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99248099; called by muse, mutect2, varscan2
- HENMT1 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV100898637, COSV64230584; called by muse, mutect2
- HEPACAM | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV100005425; called by muse, mutect2
- HEPH | c.1850C>T p.S617F (on ENST00000343002; = p.S350F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100294026; called by muse, mutect2, varscan2
- HHIP | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs746714216, COSV56836455; called by muse, mutect2, varscan2
- HKDC1 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100664349; called by muse, mutect2, varscan2
- HNF4G | c.231G>A p.M77I (on ENST00000354370 / NM_001330561.2; = p.M124I on NM_004133.5) | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs867924573, COSV100584026; called by muse, mutect2, varscan2
- HNRNPH3 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.755); catalogued as COSV99769106; called by muse, mutect2, varscan2
- IFNA16 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 91/148 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs773023838, COSV66510680; called by muse, mutect2, varscan2
- IGFL1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101473050; called by muse, mutect2, varscan2
- IGHV2-26 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1192034416; called by muse, mutect2, varscan2
- IGSF1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as rs749000372, COSV100811790; called by muse, mutect2, varscan2
- IGSF9B | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV58074886; called by muse, mutect2, varscan2
- IKZF2 | c.798A>G p.I266M | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100563152; called by muse, mutect2, varscan2
- IL17RD | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770777224, COSV99576507; called by muse, mutect2, varscan2
- IL25 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1461024540, COSV100197909; called by muse, mutect2, varscan2
- IPO5 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as COSV99846948; called by muse, mutect2, varscan2
- IQCN | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1324617774, COSV101148323; called by muse, mutect2, varscan2
- ITGA4 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV99275685; called by muse, mutect2, varscan2
- ITK | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101439585; called by muse, mutect2, varscan2
- ITM2C | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV100419546; called by muse, mutect2, varscan2
- JAK3 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs201972084, COSV71687119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAKMIP1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1384162757, COSV99288559; called by muse, mutect2, varscan2
- JPH2 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100881573; called by muse, mutect2, varscan2
- KBTBD12 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100675345; called by muse, mutect2, varscan2
- KBTBD13 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as rs1270566995; called by muse, mutect2, varscan2
- KCNA6 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54978785; called by muse, varscan2
- KCNA6 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.045); catalogued as COSV54976835; called by muse, mutect2, varscan2
- KCNQ4 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV61272519; called by muse, mutect2, varscan2
- KCNT2 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 78/113 reads (69%) | catalogued as COSV54093604; called by muse, mutect2, varscan2
- KDM3B | c.3965C>T p.S1322F | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100069130; called by muse, mutect2, varscan2
- KHDRBS2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1475247394, COSV99830701; called by muse, mutect2, varscan2
- KIAA0232 | c.3883C>T p.P1295S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100300319; called by muse, mutect2, varscan2
- KIF3A | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1486476976, COSV101109211; called by muse, mutect2, varscan2
- KIF9 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV99646329; called by muse, mutect2, varscan2
- KITLG | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 66/75 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1479672313, COSV99933095; called by muse, mutect2, varscan2
- KLRK1 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV99555000; called by muse, mutect2, varscan2
- KMT2D | c.7153C>T p.P2385S | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99977221; called by muse, mutect2, varscan2
- KNG1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV99405065; called by muse, mutect2, varscan2
- KRIT1 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs749565503, COSV100388583; called by muse, mutect2, varscan2
- KRTAP10-10 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs782527032, COSV59962361; called by muse, mutect2, varscan2
- L3HYPDH | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.389); catalogued as COSV99904320; called by muse, mutect2, varscan2
- LAG3 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99179874; called by muse, mutect2, varscan2
- LAMA1 | c.8762G>A p.R2921Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs371871409; called by muse, mutect2, varscan2
- LAMC1 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265525294, COSV99278872; called by muse, mutect2, varscan2
- LAMC2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368028478; called by muse, mutect2, varscan2
- LBR | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1367356844, COSV99687161; called by muse, mutect2, varscan2
- LEPR | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as rs867390691, COSV100756252; called by muse, mutect2, varscan2
- LILRB2 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100078952, COSV58747772; called by muse, mutect2, varscan2
- LIMCH1 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100573331; called by muse, mutect2, varscan2
- LINGO4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV100561784; called by muse, mutect2, varscan2
- LNPEP | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99183466; called by muse, mutect2, varscan2
- LOX | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV50239356; called by muse, mutect2, varscan2
- LPA | c.4940G>C p.R1647P | Missense Mutation (SNP) | VAF 69/86 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV100305995; called by muse, mutect2, varscan2
- LRFN5 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982410; called by muse, mutect2
- LRP4 | c.5053C>T p.R1685W | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as rs143717815; called by muse, mutect2, varscan2
- LRRC15 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61650592; called by muse, mutect2, varscan2
- LRRC37B | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 136/151 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100495988; called by muse, mutect2, varscan2
- LRRC4C | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53424272; called by muse, mutect2, varscan2
- LRRC7 | c.1570G>A p.E524K (on ENST00000651989 / NM_001370785.2; = p.E491K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs866086728, COSV50412443; called by muse, mutect2, varscan2
- LRRC8C | c.1997C>A p.S666Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767069826, COSV100967985; called by muse, mutect2, varscan2
- LRRIQ1 | c.2831C>T p.T944I | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV101279418, COSV67836186; called by muse, mutect2, varscan2
- LRRIQ4 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs774922199, COSV100540059; called by muse, mutect2, varscan2
- LST1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs758818205, COSV99278852; called by muse, mutect2, varscan2
- LTBP1 | c.1537G>A p.E513K (on ENST00000404816 / NM_206943.4; = p.E187K on NM_000627.4) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.079); catalogued as COSV100616222; called by muse, mutect2, varscan2
- LY9 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 123/201 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99626149; called by muse, mutect2, varscan2
- MAP9 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV100250697; called by muse, mutect2, varscan2
- MB | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355627393, COSV100704680; called by muse, mutect2, varscan2
- MECOM | c.1023G>A p.M341I (on ENST00000468789 / NM_001105078.4; = p.M529I on NM_004991.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV52974391; called by muse, mutect2, varscan2
- MED12L | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV99851393; called by muse, mutect2, varscan2
- MEGF8 | c.7610C>T p.P2537L (on ENST00000251268 / NM_001271938.2; = p.P2470L on NM_001410.3) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774730847, COSV99234264; called by muse, mutect2, varscan2
- MELK | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV99974168; called by muse, mutect2, varscan2
- METTL22 | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99371514; called by muse, mutect2, varscan2
- MFSD2A | c.361C>T p.P121S (on ENST00000372809 / NM_001136493.3; = p.P108S on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/247 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1403639907, COSV65685843; called by muse, mutect2, varscan2
- MGAT1 | c.1256T>A p.I419N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | PolyPhen probably damaging (0.997); catalogued as COSV100286499; called by muse, mutect2, varscan2
- MIOS | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.038); catalogued as rs773014725, COSV100402541; called by muse, mutect2, varscan2
- MMP12 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV58261792; called by muse, mutect2, varscan2
- MOCOS | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771446328, COSV99732732; called by muse, mutect2
- MORN5 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055646; called by muse, mutect2, varscan2
- MOV10L1 | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99432521; called by muse, mutect2, varscan2
- MPP6 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1355816586, COSV99757089; called by muse, mutect2, varscan2
- MPZL2 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99634952; called by muse, mutect2, varscan2
- MTTP | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV99644726; called by muse, mutect2
- MUC16 | c.11284G>A p.E3762K | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as COSV67473468; called by muse, mutect2, varscan2
- MUC16 | c.8183C>T p.S2728F | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67488335; called by muse, mutect2, varscan2
- MUC16 | c.7930C>T p.L2644F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as rs757186397, COSV101197963; called by muse, mutect2, varscan2
- MUC16 | c.1840G>A p.G614S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); catalogued as COSV101197964; called by muse, mutect2, varscan2
- MUC16 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV101197965; called by muse, mutect2, varscan2
- MYH4 | c.4313G>A p.R1438Q | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs139449510, COSV55116187; called by muse, mutect2, varscan2
- MYH8 | c.4988C>T p.A1663V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV101238129; called by muse, mutect2, varscan2
- MYO5C | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770658599, COSV99954012; called by muse, mutect2, varscan2
- NALCN | c.2457G>A p.R819= | Splice Region (SNP) | VAF 16/74 reads (22%) | catalogued as rs868262120, COSV99212824; called by muse, mutect2, varscan2
- NBEA | c.8456G>A p.G2819E | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100076482; called by muse, mutect2, varscan2
- NCAPH2 | c.423G>A p.E141= | Splice Region (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100237868; called by muse, mutect2, varscan2
- NCBP3 | c.1106T>G p.V369G | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99339260; called by muse, mutect2, varscan2
- NCKAP1L | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as COSV99514380; called by muse, mutect2, varscan2
- NCKAP5 | c.5403G>A p.M1801I | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100489872; called by muse, mutect2, varscan2
- NDNF | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.321); catalogued as COSV101113086; called by muse, mutect2, varscan2
- NEBL | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1015396131, COSV101009073; called by muse, mutect2, varscan2
- NECAP2 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100452229; called by muse, mutect2, varscan2
- NEK9 | c.2437C>T p.R813* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs779892471, COSV53133752; called by muse, mutect2, varscan2
- NELL2 | c.1662G>A p.T554= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as rs756487539, COSV100418602; called by muse, mutect2, varscan2
- NETO1 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV55000890; called by muse, mutect2, varscan2
- NFATC1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99500460; called by muse, mutect2, varscan2
- NKAIN3 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60682031, COSV60691994; called by muse, mutect2, varscan2
- NLGN3 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100704532; called by muse, mutect2, varscan2
- NLRP13 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866889624, COSV61620245; called by muse, mutect2, varscan2
- NLRP5 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV101173333; called by muse, mutect2, varscan2
- NMD3 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1446093945, COSV100664592, COSV63618734; called by muse, mutect2, varscan2
- NOX3 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1270453721, COSV99342662; called by muse, mutect2, varscan2
- NOX5 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV99533207; called by muse, mutect2, varscan2
- NPAS4 | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100214752; called by muse, mutect2, varscan2
- NPSR1 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs749301919, COSV100705674; called by muse, mutect2, varscan2
- NRAP | c.2500A>T p.I834F (on ENST00000359988 / NM_001322945.2; = p.I799F on NM_006175.4) | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100748250; called by muse, mutect2
- NRP2 | c.2491+1G>A p.X831_splice (on ENST00000360409 / NM_201266.2; = p.X826_splice on NM_003872.3) | Splice Site (SNP) | VAF 30/139 reads (22%) | catalogued as COSV100760415; called by muse, mutect2, varscan2
- NSD1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100728376; called by muse, mutect2, varscan2
- OBSCN | c.15286C>T p.R5096W | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs761762316, COSV99471981; called by muse, mutect2, varscan2
- OIT3 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1189377325, COSV61825743; called by muse, mutect2, varscan2
- ONECUT2 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1372284022, COSV101525681; called by muse, mutect2, varscan2
- OR10S1 | c.488G>T p.W163L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV101602442; called by muse, mutect2, varscan2
- OR1Q1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV52917786, COSV99939167; called by muse, mutect2, varscan2
- OR2L13 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 125/213 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV63562019; called by muse, mutect2, varscan2
- OR2T33 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs756717060, COSV58814950; called by muse, mutect2, varscan2
- OR2T34 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV100170219; called by muse, mutect2, varscan2
- OR4C15 | c.938G>A p.R313Q (on ENST00000314644; = p.R259Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as rs149965163, COSV58952933, COSV58954574; called by muse, mutect2, varscan2
- OR4X2 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100183146; called by muse, mutect2, varscan2
- OR51D1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100712340; called by muse, mutect2, varscan2
- OR51V1 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866961237, COSV58315699; called by muse, varscan2
- OR52E8 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 53/96 reads (55%) | catalogued as rs749432707, COSV101189967; called by muse, mutect2, varscan2
- OR52N2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344772308, COSV57677180; called by muse, mutect2, varscan2
- OR52N5 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 71/108 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100399585; called by muse, mutect2, varscan2
- OR6K3 | c.248C>T p.S83F (on ENST00000368146; = p.S67F on NM_001005327.2) | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63745649; called by muse, mutect2, varscan2
- OR6Q1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761582438, COSV56933080; called by muse, mutect2, varscan2
- OR7D2 | c.811A>T p.I271F | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.255); catalogued as COSV100712929; called by muse, varscan2
- OR8A1 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.042); catalogued as COSV99420273; called by muse, mutect2, varscan2
- OSBP | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353247419, COSV55661776, COSV99803094; called by muse, mutect2, varscan2
- OSBPL10 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as rs1403587806, COSV67338052; called by muse, mutect2, varscan2
- OVOL2 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99602317; called by muse, mutect2, varscan2
- OXA1L | c.956C>T p.S319F (on ENST00000285848; = p.S259F on NM_005015.5) | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV99590986; called by muse, mutect2, varscan2
- OXGR1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53657151, COSV53657698; called by muse, mutect2, varscan2
- PABPC4 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as rs751631876, COSV65724441; called by muse, mutect2, varscan2
- PAH | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100187582; called by muse, mutect2, varscan2
- PAK5 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV100781059; called by muse, mutect2, varscan2
- PAPPA2 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV62772131; called by muse, mutect2, varscan2
- PAX1 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101270190; called by muse, mutect2, varscan2
- PAX1 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147752664; called by muse, mutect2, varscan2
- PBX3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as rs757125897, COSV100655249; called by muse, mutect2, varscan2
- PCDH15 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs1281151581, COSV57287031; called by muse, mutect2, varscan2
- PCDH18 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.755); catalogued as COSV61270156, COSV61271158; called by muse, mutect2, varscan2
- PCDHA1 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 62/144 reads (43%) | catalogued as COSV100974250; called by muse, varscan2
- PCDHA12 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.364); catalogued as rs1554168093, COSV56475083; called by muse, mutect2, varscan2
- PCDHA6 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.178); catalogued as COSV100972073; called by muse, mutect2, varscan2
- PCDHGA12 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1462942281, COSV99337653; called by muse, mutect2, varscan2
- PCDHGB3 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.107); catalogued as COSV99529759; called by muse, mutect2, varscan2
- PCSK5 | c.5515G>A p.G1839R | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101377237; called by muse, mutect2, varscan2
- PDE1A | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100112770; called by muse, mutect2, varscan2
- PDE6A | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99677728; called by muse, mutect2, varscan2
- PDILT | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1373532778, COSV56703412; called by muse, mutect2, varscan2
- PER3 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.173); catalogued as COSV100728198; called by muse, varscan2
- PHACTR3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1332569140, COSV63025673; called by muse, mutect2, varscan2
- PIP5K1B | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs1381996000, COSV99597884; called by muse, mutect2, varscan2
- PLA2G4F | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99300306; called by muse, mutect2, varscan2
- PLAAT2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV99738037; called by muse, mutect2, varscan2
- PLAUR | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV99654967; called by muse, mutect2, varscan2
- PLB1 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100214762; called by muse, mutect2, varscan2
- PLEC | c.9599G>A p.G3200D (on ENST00000322810 / NM_201380.4; = p.G3090D on NM_000445.5) | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as rs1554682467, COSV100510214; called by muse, mutect2, varscan2
- PMFBP1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs552686844, COSV52828530; called by muse, mutect2, varscan2
- PNPLA2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100351921; called by muse, mutect2, varscan2
- POM121 | c.1563G>A p.L521= (on ENST00000434423; = p.L256= on NM_172020.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 13/91 reads (14%) | catalogued as COSV99987495; called by muse, mutect2, varscan2
- PPDPFL | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 66/105 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57461684; called by muse, mutect2, varscan2
- PPP4R4 | c.374T>G p.V125G | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100175583; called by muse, mutect2, varscan2
- PRAMEF12 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.287); catalogued as COSV100742978; called by muse, mutect2, varscan2
- PRB2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV101231364; called by muse, mutect2, varscan2
- PRKAA2 | c.895A>C p.K299Q | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100982749; called by muse, mutect2, varscan2
- PRKAR1A | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs1310506395, COSV100675060; called by muse, mutect2, varscan2
- PRKG1 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100907494, COSV64770226; called by muse, mutect2, varscan2
- PROSER3 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.692); catalogued as COSV99994437; called by muse, mutect2, varscan2
- PROZ | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs935408702, COSV100720257; called by muse, mutect2, varscan2
- PRPF6 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1261847848, COSV53869661, COSV53874434; called by muse, mutect2, varscan2
- PRRC2A | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV100784519; called by muse, mutect2, varscan2
- PRSS55 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.8); catalogued as COSV100153603; called by muse, mutect2, varscan2
- PSD4 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs112233668, COSV99830791; called by muse, mutect2, varscan2
- PSG6 | c.245A>T p.Y82F | Missense Mutation (SNP) | VAF 100/404 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV99413490; called by muse, mutect2
- PSMD5 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs769588828, COSV99270629; called by muse, mutect2, varscan2
- PTPN22 | c.2068C>T p.R690C (on ENST00000359785 / NM_001193431.2; = p.R635C on NM_012411.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs200154470, COSV63085044; called by muse, mutect2, varscan2
- PTPN3 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769107972, COSV99355356; called by muse, mutect2, varscan2
- PTPRC | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313856921, COSV100722003; called by muse, mutect2, varscan2
- PTPRF | c.2273G>A p.G758E | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV63444273; called by muse, mutect2, varscan2
- PTPRT | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 40/207 reads (19%) | catalogued as COSV100624889; called by muse, mutect2, varscan2
- PUDP | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.317); catalogued as rs1485258841, COSV101127773; called by muse, mutect2, varscan2
- RARB | c.1034C>T p.P345L (on ENST00000383772 / NM_001290216.2; = p.P338L on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV99979062; called by muse, mutect2, varscan2
- RASA3 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100479692; called by muse, mutect2, varscan2
- RASAL1 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs149283617, COSV55654342; called by muse, mutect2, varscan2
- RASGEF1C | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.234); catalogued as rs775373995, COSV100745513; called by muse, varscan2
- RBM10 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV100237246; called by muse, mutect2, varscan2
- RBM28 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751906113, COSV99775451; called by muse, mutect2, varscan2
- RELB | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV99672690; called by muse, mutect2, varscan2
- REPS2 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs1450833779, COSV100380780, COSV99061270; called by muse, mutect2, varscan2
- REV3L | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100724824; called by muse, mutect2, varscan2
- RFPL2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.51); catalogued as rs754522150, COSV99963994; called by muse, mutect2, varscan2
- RFX6 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.051); catalogued as COSV100263175, COSV100264033; called by muse, mutect2, varscan2
- RFX6 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263177; called by muse, mutect2, varscan2
- RGS12 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs768665650, COSV100374679; called by muse, mutect2, varscan2
- RGS22 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769915133, COSV62663897, COSV62670293; called by muse, mutect2, varscan2
- RND1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs144289367; called by muse, mutect2, varscan2
- RNF133 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 97/290 reads (33%) | catalogued as rs1396161513, COSV100411416, COSV57361361; called by muse, mutect2, varscan2
- RNF220 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100698283; called by muse, mutect2, varscan2
- ROBO3 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs1409923663, COSV101184883; called by muse, mutect2, varscan2
- ROS1 | c.6913G>A p.E2305K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.19); catalogued as COSV100876335; called by muse, mutect2, varscan2
- RP1L1 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 73/108 reads (68%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs1348223070, COSV101222907; called by muse, mutect2, varscan2
- RPLP0 | c.361G>T p.V121F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99935234; called by muse, mutect2
- RPRD2 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV100954865; called by muse, mutect2, varscan2
- RPS20 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1384442441, COSV99154728; called by muse, mutect2, varscan2
- RSAD1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs754286924, COSV99364098; called by muse, mutect2, varscan2
- RSL1D1 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs781117638, COSV100851926; called by muse, mutect2, varscan2
- RUNDC3B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.917); catalogued as rs756808827, COSV55945690; called by muse, mutect2, varscan2
- RYR1 | c.9174G>A p.G3058= | Splice Region (SNP) | VAF 15/35 reads (43%) | catalogued as rs1454302886, COSV100614305; called by muse, mutect2, varscan2
- RYR2 | c.12892G>A p.V4298M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs745927659, CM108884, COSV63710483, COSV63711482; called by muse, mutect2, varscan2
- SAMD14 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99142903; called by muse, mutect2, varscan2
- SAMSN1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1415886428, COSV99580583; called by muse, mutect2, varscan2
- SAP30L | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs201712433, COSV51737242; called by muse, mutect2, varscan2
- SCN10A | c.4281G>A p.K1427= | Splice Region (SNP) | VAF 73/174 reads (42%) | catalogued as COSV101479228; called by mutect2, varscan2
- SCN3A | c.3448C>G p.R1150G | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV99325551; called by muse, mutect2, varscan2
- SDR16C5 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768577847, COSV100373748, COSV58128567; called by muse, mutect2, varscan2
- SEC16A | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs780952432, COSV99255979; called by muse, mutect2, varscan2
- SELPLG | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV99947211; called by muse, mutect2, varscan2
- SELPLG | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as rs1265623487, COSV99947215; called by mutect2, varscan2
- SEMA3E | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1049236480, COSV100317149; called by muse, mutect2, varscan2
- SENP7 | c.3100C>T p.R1034* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as rs144603399; called by muse, mutect2, varscan2
- SERPINB13 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs754682449, COSV54027886; called by muse, mutect2
- SERPINB3 | c.351G>A p.Q117= | Splice Region (SNP) | VAF 58/150 reads (39%) | catalogued as rs1426737256; called by mutect2, varscan2
- SERPINB5 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs1275909068, COSV66976229; called by muse, mutect2, varscan2
- SEZ6L | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99961270; called by muse, mutect2, varscan2
- SH2D3A | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV55587271; called by muse, mutect2, varscan2
- SH3GL2 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs367593553; called by muse, mutect2, varscan2
- SH3GL3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs373378258; called by muse, mutect2, varscan2
- SHANK1 | c.6106C>T p.R2036C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs764924872, COSV99520106; called by muse, mutect2, varscan2
- SHB | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs778891600, COSV66628274; called by muse, mutect2, varscan2
- SI | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100013788; called by muse, mutect2, varscan2
- SLA | c.85G>A p.V29M (on ENST00000338087 / NM_001045556.3; = p.V69M on NM_006748.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758614889, COSV99598810; called by muse, mutect2, varscan2
- SLAMF9 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100928100; called by muse, mutect2, varscan2
- SLC12A3 | c.504C>T p.I168= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as rs202087190, COSV99343801; called by muse, mutect2
- SLC16A7 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs749085265, COSV53900819; called by muse, mutect2, varscan2
- SLC16A9 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101264295; called by muse, mutect2, varscan2
- SLC17A2 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as rs1033208738, COSV99613847; called by muse, mutect2, varscan2
- SLC17A6 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54137362, COSV54141234; called by muse, mutect2, varscan2
- SLC17A8 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV60124975; called by muse, mutect2, varscan2
- SLC26A7 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52591621; called by muse, mutect2, varscan2
- SLC34A1 | c.1450G>A p.G484S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1334378226, COSV99499398; called by muse, mutect2, varscan2
- SLC35F3 | c.926C>T p.S309L (on ENST00000366617 / NM_001300845.1; = p.S378L on NM_173508.4) | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100784692; called by muse, mutect2, varscan2
- SLC3A1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1266621109, CM1111548, COSV99576797, COSV99577757; called by muse, mutect2, varscan2
- SLC4A11 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV101195876; called by muse, mutect2, varscan2
- SLC4A11 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV101195877; called by muse, mutect2, varscan2
- SLC4A8 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1423260738, COSV100176407; called by muse, mutect2
- SLC5A10 | c.1216G>A p.E406K (on ENST00000395645 / NM_001042450.4; = p.E422K on NM_152351.5) | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs768817506, COSV100524771; called by muse, mutect2, varscan2
- SLC6A11 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV54399657; called by muse, mutect2, varscan2
- SLC6A19 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs773280349, COSV58671944; called by muse, varscan2
- SLC8A3 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100775859; called by muse, mutect2, varscan2
- SLC9A4 | c.2159G>A p.R720K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs769775586, COSV54830380; called by muse, mutect2, varscan2
- SLCO2A1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100188632; called by muse, mutect2, varscan2
- SLFN13 | c.1877G>A p.R626K | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV53194411, COSV99539699; called by muse, mutect2, varscan2
- SLK | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs150455513, COSV59823818; called by muse, mutect2, varscan2
- SLU7 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.841); catalogued as rs781098293, COSV99775426; called by muse, mutect2, varscan2
- SMG7 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100750048; called by muse, mutect2, varscan2
- SMURF2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568303941, COSV52314549; called by muse, mutect2, varscan2
- SNAP91 | c.2041T>A p.S681T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV99534227; called by muse, varscan2
- SNAP91 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99534232; called by muse, varscan2
- SNRK | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV99938789; called by muse, mutect2, varscan2
- SNRNP200 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV100107061; called by muse, mutect2, varscan2
- SOGA3 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV64104970; called by muse, mutect2, varscan2
- SORCS3 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63803272; called by muse, mutect2, varscan2
- SPANXD | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100982240; called by muse, varscan2
- SPANXD | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1180897900, COSV65152248, COSV65152621; called by muse, varscan2
- SPATA16 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs866699596, COSV100650844, COSV100651435; called by muse, mutect2, varscan2
- SPATA31D1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as COSV100782450; called by muse, mutect2, varscan2
- SPEF2 | c.3110C>T p.S1037F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs752773618, COSV61547667; called by muse, mutect2, varscan2
- SPEF2 | c.4375G>A p.E1459K | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV100288701; called by muse, mutect2, varscan2
- SRGAP3 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1278213239, COSV100840676; called by muse, mutect2, varscan2
- SS18L1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as rs777905619, COSV100064424; called by muse, varscan2
- ST6GAL2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 82/215 reads (38%) | PolyPhen probably damaging (0.99); catalogued as rs1473596085, COSV100699508; called by muse, mutect2, varscan2
- STAB1 | c.6556G>A p.G2186S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as COSV100194488; called by muse, mutect2, varscan2
- STAU1 | c.1302T>A p.H434Q (on ENST00000371856 / NM_001319135.1; = p.H353Q on NM_004602.3) | Missense Mutation (SNP) | VAF 82/103 reads (80%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100574254; called by muse, mutect2, varscan2
- STEAP4 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV100112362; called by muse, mutect2, varscan2
- STIL | c.2920C>T p.Q974* | Nonsense Mutation (SNP) | VAF 92/148 reads (62%) | catalogued as COSV99680545; called by muse, mutect2, varscan2
- STON1 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as rs749832371, COSV100561429; called by muse, mutect2, varscan2
- STRIP2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99973427; called by muse, mutect2, varscan2
- STXBP5L | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99871848; called by muse, mutect2, varscan2
- SULF1 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99481993; called by muse, mutect2, varscan2
- SULT1C4 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as COSV55598312; called by muse, mutect2, varscan2
- SUSD2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs139630528; called by muse, mutect2, varscan2
- SVIL | c.3263C>T p.S1088F (on ENST00000355867 / NM_021738.3; = p.S662F on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.169); catalogued as COSV100880859; called by muse, mutect2, varscan2
- SYNE3 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs369096132; called by muse, mutect2
- SZT2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368761999, COSV60290526; called by muse, mutect2, varscan2
- SZT2 | c.7925G>A p.R2642Q (on ENST00000634258 / NM_001365999.1; = p.R2585Q on NM_015284.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs752527663, COSV100986863; called by muse, mutect2, varscan2
- TAAR6 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51584112; called by muse, mutect2, varscan2
- TARBP1 | c.4732C>T p.Q1578* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99241021; called by muse, mutect2, varscan2
- TBC1D1 | c.2593C>A p.Q865K | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99790391; called by muse, mutect2
- TBC1D13 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs139504114; called by muse, mutect2, varscan2
- TDRD5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV99675364; called by muse, mutect2, varscan2
- TECTB | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as rs372410453; called by muse, mutect2, varscan2
- TEX30 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as rs573603152, COSV101051943; called by muse, mutect2, varscan2
- TEX37 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100304565; called by muse, mutect2, varscan2
- TEX47 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1455377109, COSV51878120, COSV99787158; called by muse, mutect2, varscan2
- TF | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.122); catalogued as rs773144601, COSV53920891, COSV99395321; called by muse, mutect2, varscan2
- TGS1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | catalogued as COSV99485018; called by muse, mutect2, varscan2
- THBS2 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.535); catalogued as rs747682831, COSV64678080, COSV64681282; called by muse, mutect2, varscan2
- THBS3 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103819, COSV100104383; called by muse, mutect2, varscan2
- THSD7A | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); catalogued as rs1254817926, COSV101448531; called by muse, mutect2
- TIA1 | c.398C>T p.S133L (on ENST00000433529 / NM_001351511.1; = p.S122L on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs375191972, COSV99248339; called by muse, mutect2, varscan2
- TIAM1 | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99732515; called by muse, mutect2, varscan2
- TJP3 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1411088679, COSV99515698; called by muse, mutect2
- TLR8 | c.166G>A p.E56K (on ENST00000218032 / NM_138636.5; = p.E74K on NM_016610.4) | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV54319986; called by muse, mutect2, varscan2
- TLR8 | c.1490G>A p.G497E (on ENST00000218032 / NM_138636.5; = p.G515E on NM_016610.4) | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as COSV99486747; called by muse, mutect2, varscan2
- TMA16 | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1382659327, COSV100667275; called by muse, mutect2, varscan2
- TMC5 | c.1445A>T p.N482I (on ENST00000396229 / NM_001105248.1; = p.N236I on NM_024780.5) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99572139; called by muse, mutect2, varscan2
- TMEFF1 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 98/177 reads (55%) | catalogued as rs200469769, COSV100293099; called by muse, mutect2, varscan2
- TMEFF2 | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1399339845, COSV99770898; called by muse, mutect2, varscan2
- TMEM131L | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV99546714; called by muse, mutect2, varscan2
- TMEM131L | c.3508C>T p.H1170Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV99546716; called by muse, mutect2, varscan2
- TMEM132D | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs759524697, COSV70609077; called by muse, mutect2, varscan2
- TMEM45A | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as COSV100058051; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3773C>T p.T1258I | Missense Mutation (SNP) | VAF 98/168 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs1374269457, COSV100835777; called by muse, mutect2, varscan2
- TNNI2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV99425316; called by muse, mutect2, varscan2
- TNRC6C | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 126/138 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100049424; called by muse, mutect2, varscan2
- TOX3 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV99567004; called by muse, mutect2, varscan2
- TP63 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.15); catalogued as rs767553568, COSV53204862; called by muse, mutect2, varscan2
- TPRX1 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.192); catalogued as COSV100445480; called by muse, mutect2, varscan2
- TPTE | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1255945263; called by muse, mutect2, varscan2
- TPTE | c.269C>T p.S90L (on ENST00000618007 / NM_199261.4; = p.S72L on NM_199259.4) | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs773649955; called by muse, mutect2, varscan2
- TPTE | c.1340C>T p.S447L (on ENST00000618007 / NM_199261.4; = p.S429L on NM_199259.4) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs759301774; called by muse, mutect2, varscan2
- TPTE2 | c.1466G>A p.R489K (on ENST00000400230 / NM_199254.2; = p.R412K on NM_130785.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV55023300, COSV99690535; called by muse, mutect2, varscan2
- TRANK1 | c.4306G>A p.D1436N | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780451778, COSV100081317; called by muse, mutect2, varscan2
- TRDN | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs1338366076, COSV62126646; called by muse, mutect2, varscan2
- TRERF1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as COSV100549889; called by muse, mutect2, varscan2
- TRERF1 | c.1126C>A p.Q376K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs1477822643, COSV100549891; called by muse, mutect2, varscan2
- TRHDE | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs771688480, COSV53831518; called by muse, mutect2, varscan2
- TRIM5 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs751106763, COSV99999947; called by muse, varscan2
- TRIP11 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1043673635, COSV99970284; called by muse, mutect2, varscan2
- TRPC3 | c.1225G>A p.E409K (on ENST00000379645 / NM_001366479.2; = p.E336K on NM_003305.2) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99312065; called by muse, mutect2, varscan2
- TRPM6 | c.5134+1G>C p.X1712_splice | Splice Site (SNP) | VAF 43/73 reads (59%) | catalogued as COSV100665199; called by muse, mutect2, varscan2
- TRPM7 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV100539345; called by muse, mutect2, varscan2
- TSHZ2 | c.1285A>T p.M429L | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100295322; called by muse, mutect2, varscan2
- TTC21A | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100072938; called by muse, mutect2, varscan2
- TTC27 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100512610; called by muse, mutect2, varscan2
- TTLL4 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV99292984; called by muse, mutect2, varscan2
- TTN | c.99862G>A p.E33288K (on ENST00000591111; = p.E25864K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | PolyPhen possibly damaging (0.73); catalogued as COSV100592771; called by muse, mutect2, varscan2
- TTN | c.67975G>A p.E22659K (on ENST00000591111; = p.E15235K on NM_003319.4) | Missense Mutation (SNP) | VAF 75/153 reads (49%) | PolyPhen probably damaging (0.994); catalogued as COSV100592775; called by muse, mutect2, varscan2
- TTN | c.67591A>T p.N22531Y (on ENST00000591111; = p.N15107Y on NM_003319.4) | Missense Mutation (SNP) | VAF 87/411 reads (21%) | PolyPhen possibly damaging (0.515); catalogued as COSV100592778; called by muse, mutect2, varscan2
- TTN | c.45451G>A p.E15151K (on ENST00000591111; = p.E7727K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | PolyPhen probably damaging (0.994); catalogued as COSV100592781; called by muse, mutect2, varscan2
- TTN | c.33169G>A p.E11057K (on ENST00000591111; = p.E10130K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/178 reads (44%) | PolyPhen benign (0.021); catalogued as rs1442680264, COSV100592783; called by muse, mutect2, varscan2
- TTN | c.25386A>T p.E8462D (on ENST00000591111; = p.E7535D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | PolyPhen benign (0); catalogued as COSV100592784; called by muse, mutect2, varscan2
- TTN | c.14807G>A p.G4936E (on ENST00000591111; = p.G4009E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | PolyPhen possibly damaging (0.866); catalogued as COSV100592787; called by muse, mutect2, varscan2
- TTN | c.11743G>A p.E3915K (on ENST00000591111; = p.E3869K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100592789; called by muse, mutect2, varscan2
- UBN1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs747689569, COSV99277395; called by muse, mutect2, varscan2
- UGT2A1 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as rs752980867, COSV54142675; called by muse, mutect2, varscan2
- UGT2B11 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 39/252 reads (15%) | catalogued as rs764600893, COSV101485241, COSV71423508, COSV71423771; called by muse, varscan2
- UGT2B7 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100535093; called by muse, mutect2, varscan2
- UMODL1 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100210505; called by muse, mutect2, varscan2
- UNC13C | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs267604261, COSV52899721, COSV52907623; called by muse, mutect2, varscan2
- UNC79 | c.6652G>A p.E2218K (on ENST00000393151 / NM_001346218.2; = p.E2041K on NM_020818.5) | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs1243144985, COSV56374372; called by muse, mutect2, varscan2
- USP54 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs774832606, COSV100160875; called by muse, mutect2, varscan2
- USP54 | c.1386G>C p.R462S | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100160878; called by muse, mutect2, varscan2
- VARS1 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1238999547, COSV100989862; called by muse, mutect2, varscan2
- VCAM1 | c.1312A>T p.I438F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99658156; called by muse, mutect2
- VCAN | c.6116C>T p.S2039F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV99424515; called by muse, mutect2, varscan2
- VLDLR | c.2088A>T p.E696D | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.684); catalogued as COSV101173440; called by muse, mutect2, varscan2
- VLDLR | c.2089C>T p.L697F | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101173441; called by muse, mutect2, varscan2
- VWF | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478975030, COSV54633323; called by muse, mutect2, varscan2
- VWF | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as COSV99777836; called by muse, mutect2, varscan2
- WDR24 | c.1295G>A p.G432E (on ENST00000248142; = p.G302E on NM_032259.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99555348; called by muse, mutect2, varscan2
- WDR49 | c.2017G>A p.E673K (on ENST00000308378 / NM_001366158.1; = p.E1014K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs1373560612, COSV52984038; called by muse, mutect2, varscan2
- WNK2 | c.6863C>T p.S2288F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99940830; called by muse, mutect2, varscan2
- WNK3 | c.4418G>A p.S1473N | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV63614818; called by muse, mutect2, varscan2
- XK | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT tolerated (0.53); PolyPhen benign (0.083); catalogued as COSV101064513, COSV66119691; called by muse, mutect2, varscan2
- XKR6 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs780603148, COSV58655573; called by muse, mutect2, varscan2
- ZBTB40 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1258977668, COSV100988798; called by muse, mutect2, varscan2
- ZBTB49 | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV61924802; called by muse, mutect2, varscan2
- ZDHHC5 | c.842A>T p.K281M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1402859919, COSV99762067; called by muse, mutect2, varscan2
- ZFP2 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV100796969; called by muse, mutect2, varscan2
- ZNF33B | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.974); catalogued as COSV100847577; called by muse, mutect2, varscan2
- ZNF407 | c.6163G>A p.V2055M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100224536; called by muse, mutect2, varscan2
- ZNF451 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100674565; called by muse, mutect2, varscan2
- ZNF470 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57967637; called by muse, mutect2, varscan2
- ZNF471 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs991168382, COSV100340341; called by muse, mutect2, varscan2
- ZNF496 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as COSV54177832; called by muse, mutect2, varscan2
- ZNF555 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 39/72 reads (54%) | catalogued as rs150017916; called by muse, mutect2, varscan2
- ZNF560 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs145492156, COSV100039152; called by muse, mutect2, varscan2
- ZNF560 | c.533G>A p.W178* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as rs1471622977, COSV100038209; called by muse, mutect2, varscan2
- ZNF782 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56656211; called by muse, mutect2, varscan2
- ZNF80 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as COSV57360263; called by muse, mutect2, varscan2
- ZNF804B | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs761704777, COSV60823055, COSV60857970; called by muse, mutect2, varscan2
- ZNF831 | c.3349G>T p.G1117W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64039150; called by muse, mutect2, varscan2
- ZNF831 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs754503516, COSV64043362; called by muse, mutect2, varscan2
- ZNF835 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV73379389; called by muse, mutect2, varscan2
- ZNF836 | c.1396G>T p.G466* | Nonsense Mutation (SNP) | VAF 61/210 reads (29%) | catalogued as COSV100440580, COSV59085681; called by muse, mutect2, varscan2
- ZNF91 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.081); catalogued as rs921104363, COSV100322071; called by muse, mutect2, varscan2
- ZNF98 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV63337191; called by muse, mutect2, varscan2
- ZNF98 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV100757276; called by muse, mutect2, varscan2
- ZSCAN2 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs753127034, COSV100306793; called by muse, mutect2, varscan2
- ZYG11B | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99596736; called by muse, mutect2, varscan2
- ASAH2 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRM4 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2
- DDX42 | c.1140del p.V381Cfs*7 | Frame Shift Del (DEL) | VAF 84/117 reads (72%) | called by mutect2, pindel, varscan2
- FRG2C | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FRG2C | c.679T>A p.S227T | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.115); called by muse, mutect2
- IGHV3-23 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- INPP5K | c.152+1dup p.X51_splice | Splice Site (INS) | VAF 22/37 reads (59%) | called by mutect2, pindel
- ITGA2 | c.3363_3365dup p.I1121dup | In Frame Ins (INS) | VAF 24/152 reads (16%) | called by mutect2, pindel, varscan2
- MAPK3 | c.253_258del p.T85_L86del | In Frame Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- PCDHGA3 | c.2424+7T>C | Splice Region (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- PSEN2 | c.218del p.P73Qfs*7 | Frame Shift Del (DEL) | VAF 24/41 reads (59%) | called by mutect2, pindel*, varscan2
- TRBV2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- UBE2NL | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNFX1 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- AADACL3 | c.216C>T p.F72= | Silent (SNP) | VAF 146/238 reads (61%) | catalogued as COSV100206533; called by muse, mutect2, varscan2
- ABCA13 | c.13974C>T p.F4658= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs777892727, COSV68947517; called by muse, mutect2, varscan2
- ABCC11 | c.303C>T p.T101= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV100750493; called by muse, mutect2, varscan2
- ABCC5 | c.3628C>T p.L1210= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs763508938, COSV99656331; called by muse, mutect2
- ACAN | c.7464C>G p.P2488= (on ENST00000560601 / NM_001369268.1; = p.P2450= on NM_013227.3) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100613574; called by muse, mutect2, varscan2
- ACLY | c.2220C>T p.I740= | Silent (SNP) | VAF 58/59 reads (98%) | catalogued as rs782181799, COSV100709500; called by muse, mutect2, varscan2
- ACTB | c.795C>T p.S265= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs771436794, COSV100079339; called by muse, mutect2, varscan2
- ACTRT2 | c.639G>A p.V213= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV101007471; called by muse, mutect2, varscan2
- ADAM15 | c.2361G>A p.L787= (on ENST00000356955 / NM_207197.3; = p.L762= on NM_207195.3) | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as rs779066301, COSV99664678; called by muse, mutect2, varscan2
- ADAMTS9 | c.3756G>A p.V1252= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99898633; called by muse, mutect2, varscan2
- ADGRF2 | c.1687C>T p.L563= (on ENST00000296862 / NM_001368115.2; = p.L495= on NM_153839.7) | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as COSV99730627; called by muse, mutect2, varscan2
- AFF1 | c.774C>T p.T258= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs768447096, COSV100320173; called by muse, mutect2, varscan2
- ALAS2 | c.81G>A p.K27= | Silent (SNP) | VAF 28/31 reads (90%) | catalogued as COSV100237915; called by muse, mutect2, varscan2
- ALS2CL | c.2607G>A p.S869= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs762803482, COSV59670120; called by muse, mutect2, varscan2
- ANK1 | c.4027C>T p.L1343= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV55881929; called by muse, varscan2
- AP1M2 | c.327C>T p.I109= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1379433839, COSV51569672, COSV99140947; called by muse, mutect2, varscan2
- ARHGAP25 | c.177C>T p.I59= (on ENST00000409202 / NM_001007231.3; = p.I52= on NM_014882.3) | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV54901510; called by muse, mutect2, varscan2
- ARHGAP44 | c.705T>G p.A235= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV99309999; called by muse, mutect2, varscan2
- ARHGEF17 | c.4500C>A p.S1500= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1280283197, COSV99734816; called by muse, mutect2, varscan2
- ASTN1 | c.1485G>A p.K495= | Silent (SNP) | VAF 266/462 reads (58%) | catalogued as rs1019107390, COSV99920334; called by muse, mutect2, varscan2
- ATG2A | c.1155C>T p.S385= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs754563621, COSV65967558; called by muse, mutect2, varscan2
- ATP2B4 | c.2592C>T p.I864= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as COSV100397005; called by muse, mutect2, varscan2
- ATXN3L | c.684T>C p.D228= | Silent (SNP) | VAF 82/205 reads (40%) | catalogued as COSV101019298; called by muse, mutect2, varscan2
- BCO1 | c.435G>A p.R145= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV50728291, COSV50732336; called by muse, mutect2, varscan2
- BCORL1 | c.4113C>T p.S1371= | Silent (SNP) | VAF 103/116 reads (89%) | catalogued as COSV99498350; called by muse, mutect2, varscan2
- BNIP5 | c.153G>A p.T51= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs756773124, COSV101465103; called by muse, mutect2, varscan2
- C1QTNF6 | c.786C>T p.F262= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs751679926, COSV55396199; called by muse, mutect2, varscan2
- C2CD5 | c.762C>T p.F254= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs1484437978, COSV100448436; called by muse, mutect2, varscan2
- C4B | c.3609C>T p.T1203= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV101312129; called by muse, mutect2, varscan2
- C6orf89 | c.963C>T p.T321= (on ENST00000373685; = p.T328= on NM_152734.4) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100769664; called by muse, mutect2
- CACHD1 | c.1359C>T p.F453= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as COSV99261360; called by muse, mutect2, varscan2
- CACNA1D | c.1842G>A p.G614= (on ENST00000350061 / NM_001128840.3; = p.G634= on NM_000720.4) | Silent (SNP) | VAF 51/223 reads (23%) | catalogued as rs1209404228, COSV55442926; called by muse, mutect2, varscan2
- CAMSAP3 | c.3618G>A p.S1206= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs769565176, COSV99349763; called by muse, mutect2, varscan2
- CAP2 | c.762G>A p.E254= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs547646770, COSV100012031; called by muse, mutect2, varscan2
- CARF | c.540C>T p.P180= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100247479; called by muse, mutect2, varscan2
- CCDC158 | c.1368G>A p.K456= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs949970281, COSV101187232, COSV66355493; called by muse, mutect2, varscan2
- CCDC173 | c.1401G>A p.K467= | Silent (SNP) | VAF 50/242 reads (21%) | catalogued as COSV53643034; called by muse, mutect2, varscan2
- CCDC68 | c.891C>A p.T297= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100491590; called by muse, mutect2, varscan2
- CCNA1 | c.573C>T p.L191= | Silent (SNP) | VAF 75/202 reads (37%) | catalogued as rs748507767, COSV99714269; called by muse, mutect2, varscan2
- CD1A | c.198C>T p.F66= | Silent (SNP) | VAF 73/106 reads (69%) | catalogued as rs748118650, COSV99192153, COSV99192154; called by muse, mutect2, varscan2
- CD1A | c.474C>T p.A158= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as COSV99192156; called by muse, mutect2, varscan2
- CD226 | c.573C>T p.F191= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as rs1251931474, COSV54612380; called by muse, mutect2, varscan2
- CD300E | c.96G>A p.L32= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as COSV100151147; called by muse, mutect2, varscan2
- CDC42EP4 | c.1035C>T p.F345= | Silent (SNP) | VAF 97/104 reads (93%) | catalogued as COSV100231717; called by muse, mutect2, varscan2
- CDH12 | c.711C>T p.I237= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV101201147; called by muse, mutect2, varscan2
- CDH23 | c.7158C>T p.I2386= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99818637; called by muse, mutect2, varscan2
- CEP170B | c.2850C>T p.A950= (on ENST00000453495; = p.A879= on NM_015005.3) | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs1263473397, COSV101371380; called by muse, mutect2, varscan2
- CLDN11 | c.549G>A p.Q183= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV99290890; called by muse, mutect2, varscan2
- CNTN5 | c.285G>A p.V95= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99672459; called by muse, mutect2, varscan2
- CNTNAP5 | c.1527C>T p.F509= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs765978315, COSV101442998; called by muse, mutect2, varscan2
- COL4A1 | c.2583C>T p.G861= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as rs765467440, COSV101010948; called by muse, mutect2, varscan2
- COL4A6 | c.1731G>A p.K577= | Silent (SNP) | VAF 75/86 reads (87%) | catalogued as COSV100563256; called by muse, mutect2, varscan2
- COMP | c.960G>A p.G320= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99721285; called by muse, mutect2, varscan2
- CPA3 | c.849G>A p.T283= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs200538548, COSV56047209; called by muse, mutect2, varscan2
- CPLX2 | c.78G>A p.K26= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1035106998, COSV100853002; called by muse, mutect2, varscan2
- CPXM2 | c.1599C>T p.P533= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV99580932, COSV99583610; called by muse, mutect2, varscan2
- CXCR2 | c.876C>T p.I292= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs199873547, COSV59281178; called by muse, mutect2, varscan2
- CYP2A13 | c.1152C>T p.F384= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100386617; called by muse, mutect2, varscan2
- DACT1 | c.597G>A p.A199= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs181833601; called by muse, mutect2, varscan2
- DACT1 | c.2298C>T p.F766= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs781117085, COSV60020531; called by muse, mutect2, varscan2
- DEFB129 | c.96G>A p.G32= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs1265382392, COSV99857331; called by muse, mutect2, varscan2
- DICER1 | c.1668C>T p.P556= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV100601727; called by muse, mutect2, varscan2
- DMGDH | c.159G>A p.V53= | Silent (SNP) | VAF 46/178 reads (26%) | catalogued as rs1448272269, COSV54860942, COSV54863787; called by muse, mutect2, varscan2
- DNAAF1 | c.1248C>T p.L416= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100533447; called by muse, mutect2, varscan2
- DNAH5 | c.6747C>T p.F2249= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs568499996, COSV54232083; called by muse, mutect2, varscan2
- DNAJA3 | c.1362C>T p.S454= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs369476981, COSV99276514; called by muse, mutect2, varscan2
- DNAJB12 | c.939C>T p.S313= (on ENST00000338820; = p.S279= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs373198524; called by muse, mutect2, varscan2
- DNAJC6 | c.684C>T p.F228= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as COSV99673910; called by muse, mutect2, varscan2
- DNMT1 | c.3399G>A p.E1133= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV100531685; called by muse, mutect2, varscan2
- DSCAM | c.621G>A p.T207= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs375118878, COSV68654203; called by muse, mutect2, varscan2
- DSEL | c.3267C>T p.F1089= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as rs745691476, COSV59489622, COSV59495451; called by muse, mutect2, varscan2
- DSTYK | c.2789G>A p.*930= | Silent (SNP) | VAF 79/177 reads (45%) | catalogued as COSV100904449; called by muse, mutect2, varscan2
- EBF3 | c.1443C>T p.S481= (on ENST00000355311 / NM_001375392.1; = p.S472= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV100799001; called by muse, mutect2, varscan2
- EEFSEC | c.1521G>A p.K507= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99629547; called by muse, mutect2, varscan2
295 further variants in this file (0 protein-altering or splice-affecting, 273 silent, 22 other) are not listed here.
